Somatic mutation profile of tumor specimen 0DPJT5 from CCDI case PBCDPG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Epithelioid sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 19.3 years (7,041 days).
Specimen 0DPJT5: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67aaad49-b0cd-47c3-9251-6a0a4e217bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPJS9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24cab87d-60ad-4870-a8c2-f49c7d5ce7d2

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 3, Silent 2, 3'UTR 2, Frame Shift Del 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC42BPB | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 48/422 reads (11%) | catalogued as COSV100775102; called by muse, mutect2, varscan2
- CROT | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750301718, COSV58972905; called by muse, mutect2, varscan2
- DTX1 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs760138547; called by muse, mutect2, varscan2
- FGF5 | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 28/394 reads (7%) | catalogued as rs1428956856; called by muse, mutect2
- FHDC1 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs567145547, COSV52602896, COSV99035930; called by muse, mutect2, varscan2
- FOSL1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752121425; called by muse, mutect2, varscan2
- MEX3C | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs776224061; called by muse, mutect2
- NKX2-5 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1324062610, COSV100234832; called by muse, mutect2
- SECISBP2L | c.1393A>G p.I465V (on ENST00000559471 / NM_001193489.2; = p.I420V on NM_014701.4) | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.402); catalogued as COSV55935022; called by muse, mutect2
- ZBTB20 | c.1198C>T p.R400W (on ENST00000474710 / NM_001164342.2; = p.R327W on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1481604402, COSV100614694; called by muse, mutect2
- ZNF835 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as rs759907260, COSV73379643; called by muse, mutect2, varscan2
- CFAP47 | c.8726G>C p.R2909P | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- FAM13A | c.1551del p.D518Mfs*13 | Frame Shift Del (DEL) | VAF 15/160 reads (9%) | called by mutect2, pindel, varscan2
- NDRG4 | c.151_153del p.F51del (on ENST00000570248 / NM_001378344.1; = p.F83del on NM_020465.4 and 5 other RefSeq transcripts) | In Frame Del (DEL) | VAF 42/420 reads (10%) | called by pindel, varscan2
- P2RY10 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- SZT2 | c.9166C>T p.Q3056* (on ENST00000634258 / NM_001365999.1; = p.Q2999* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 28/279 reads (10%) | called by muse, varscan2
- ZBTB42 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- LYST | c.6486C>T p.D2162= | Silent (SNP) | VAF 40/426 reads (9%) | catalogued as rs200403557, COSV67706697, COSV67712526; called by muse, mutect2
- ZMYM2 | c.1383T>A p.G461= | Silent (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- B4GALNT1 | c.*1140G>A | 3'UTR (SNP) | VAF 38/416 reads (9%) | catalogued as COSV57542074; called by muse, mutect2
- CDT1 | c.*84C>G | 3'UTR (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- MRPS18B | c.187+51A>G | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
